Somatic mutation profile of tumor specimen TCGA-EE-A2GM-06B (aliquot TCGA-EE-A2GM-06B-11D-A196-08) from TCGA case TCGA-EE-A2GM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 74.3 years (27,146 days).
Specimen TCGA-EE-A2GM-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3b83616-498e-499f-b5d1-e32683eb1742.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GM-10A (Blood Derived Normal), aliquot TCGA-EE-A2GM-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df9b914a-bb9d-4b92-a939-87794b8913e7

The open-access MAF lists 877 somatic variants for this specimen: 566 protein-altering or splice-affecting, 291 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 492, Silent 291, Nonsense Mutation 45, Splice Site 11, Splice Region 9, RNA 8, Intron 8, Frame Shift Del 5, Translation Start Site 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (750 of 877; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.5005C>T p.R1669* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs1555738369, CM101315, COSV64210783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 157/187 reads (84%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 229/366 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTSK | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 71/190 reads (37%) | catalogued as rs375958814, CM144771, CM990449, COSV55011043; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MMAA | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 24/30 reads (80%) | catalogued as rs571038432, CM043532, COSV99850081; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 89/143 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 19/21 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 49/145 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55602560; called by muse, mutect2, varscan2
- ABCB9 | c.1450G>A p.D484N (on ENST00000280560 / NM_019625.4; = p.D441N on NM_019624.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs770755585, COSV54894561; called by mutect2, varscan2
- ABCB9 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs151235593; called by muse, mutect2, varscan2
- ACO2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.167); catalogued as rs778052352, COSV53445805; called by muse, mutect2
- ACSF2 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51957658; called by muse, mutect2, varscan2
- ACSM2B | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312737, COSV61660219; called by muse, mutect2, varscan2
- ACSM5 | c.1659G>A p.V553= | Splice Region (SNP) | VAF 22/63 reads (35%) | catalogued as COSV59375340; called by muse, varscan2
- ACSS3 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.911); catalogued as rs1310073531, COSV54102471; called by muse, mutect2, varscan2
- ADAM7 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as COSV51547216; called by muse, mutect2, varscan2
- ADCY7 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99576428; called by muse, mutect2, varscan2
- ADGRF5 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV51941125; called by muse, mutect2, varscan2
- ADGRL3 | c.1341G>A p.W447* (on ENST00000506720 / NM_001322402.2; = p.W379* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as COSV72274324; called by muse, mutect2, varscan2
- ADGRV1 | c.4748C>T p.P1583L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67996478; called by muse, mutect2, varscan2
- ADRM1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV53373788; called by muse, mutect2, varscan2
- AGK | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV62596083; called by muse, mutect2, varscan2
- AGTR2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs1163188247, COSV64156615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.8123C>T p.S2708F | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484605104, COSV57233010, COSV99945931; called by muse, mutect2, varscan2
- AHNAK2 | c.8171G>A p.G2724E | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV60932574; called by muse, mutect2, varscan2
- AKR1D1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54339109; called by muse, mutect2, varscan2
- AL133500.1 | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.53); catalogued as COSV55745267; called by muse, mutect2
- ALG8 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55200760; called by muse, mutect2, varscan2
- ALPK3 | c.3295G>A p.G1099R | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs1234276224, COSV51940835; called by muse, mutect2
- AMY2B | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750106406, COSV63716287, COSV63717305; called by muse, mutect2, varscan2
- ANGPTL4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as COSV56845721; called by muse, mutect2, varscan2
- ANKEF1 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs937816950, COSV65692473, COSV65693897; called by muse, mutect2, varscan2
- ANKRD26 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.563); catalogued as COSV65799010; called by muse, mutect2, varscan2
- ANKS4B | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61140480; called by muse, mutect2, varscan2
- ANXA13 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51627012; called by muse, mutect2
- AP1B1 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369916638; called by muse, mutect2, varscan2
- AP1G1 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV55495939; called by muse, mutect2, varscan2
- APPBP2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV99319954; called by muse, mutect2, varscan2
- AQP8 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758076165, COSV54846121; called by muse, mutect2, varscan2
- ARFGEF1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51617983; called by muse, mutect2, varscan2
- ARHGEF16 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV65683405; called by muse, mutect2, varscan2
- ASH2L | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1295851732, COSV51702026; called by muse, varscan2
- ASS1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61690899; called by muse, mutect2, varscan2
- ATP2C2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV52301961; called by muse, mutect2, varscan2
- ATP4A | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52872350; called by muse, mutect2, varscan2
- ATRX | c.4459G>A p.D1487N | Missense Mutation (SNP) | VAF 78/334 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV64883431, COSV64884662; called by muse, mutect2, varscan2
- BAZ2B | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 36/161 reads (22%) | catalogued as COSV58610925; called by muse, mutect2, varscan2
- BCAT1 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1168102679, COSV53918519; called by muse, mutect2
- BCL9 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs1553202837, COSV52344530, COSV52350836; called by muse, mutect2, varscan2
- BEST3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56996314; called by muse, mutect2, varscan2
- BIN2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs775203351, COSV57208397; called by muse, mutect2, varscan2
- BLZF1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV61394811, COSV61395031; called by muse, mutect2, varscan2
- BRAF | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.419); catalogued as COSV56403182; called by muse, mutect2, varscan2
- BSN | c.8980C>T p.R2994W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765462340, COSV56512889, COSV99606846; called by muse, mutect2, varscan2
- BSN | c.10586C>T p.P3529L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV56528984; called by muse, mutect2, varscan2
- BTBD11 | c.2296G>A p.E766K (on ENST00000280758 / NM_001018072.2; = p.E303K on NM_001017523.2) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs139486003, COSV55020422; called by muse, mutect2, varscan2
- BTBD7 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV54135116; called by muse, mutect2, varscan2
- BTK | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 97/383 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.024); catalogued as COSV58124107; called by muse, mutect2, varscan2
- C10orf71 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs374875968; called by muse, mutect2, varscan2
- C16orf71 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767265532, COSV54795183; called by muse, mutect2, varscan2
- C1QTNF9 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59658308; called by muse, mutect2, varscan2
- C1QTNF9B | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65944683; called by muse, mutect2, varscan2
- C4BPA | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.638); catalogued as COSV65537843; called by muse, mutect2
- CACNA1D | c.4663C>T p.R1555* (on ENST00000350061 / NM_001128840.3; = p.R1575* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as rs562123739, COSV55466685; called by muse, mutect2, varscan2
- CACNA1E | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62385594; called by muse, mutect2, varscan2
- CACNA1S | c.4703C>T p.P1568L | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1377438279, COSV100755149, COSV62944340; called by muse, mutect2, varscan2
- CADM2 | c.679C>T p.P227S (on ENST00000407528 / NM_001167674.2; = p.P229S on NM_153184.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101053361, COSV67407947; called by muse, mutect2, varscan2
- CALB2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 138/337 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV100226461, COSV56940629; called by muse, mutect2, varscan2
- CAP2 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV57737962; called by muse, mutect2, varscan2
- CAT | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV53813595; called by muse, mutect2, varscan2
- CATSPERB | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV56429523; called by muse, mutect2, varscan2
- CCDC106 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as COSV54402840; called by muse, mutect2, varscan2
- CCDC181 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63157206; called by muse, mutect2, varscan2
- CCDC40 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV66479091; called by muse, mutect2, varscan2
- CCDC62 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53437464; called by muse, mutect2, varscan2
- CCER1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771361475, COSV62645942; called by muse, mutect2, varscan2
- CCNF | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV53543654; called by muse, mutect2, varscan2
- CCR2 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as COSV52750349; called by muse, mutect2, varscan2
- CCT8L2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63463946, COSV63463964; called by muse, mutect2, varscan2
- CD163L1 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.447); catalogued as COSV58013995; called by muse, mutect2, varscan2
- CD2 | c.952A>T p.T318S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV65644965; called by muse, mutect2, varscan2
- CD22 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50071836; called by muse, mutect2, varscan2
- CD244 | c.769G>A p.E257K (on ENST00000368033 / NM_001166663.2; = p.E252K on NM_016382.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1182804441, COSV59242018; called by muse, mutect2, varscan2
- CD8A | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs776115744, COSV52159755; called by muse, mutect2, varscan2
- CDKL5 | c.776A>C p.E259A | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as COSV66113684; called by muse, mutect2, varscan2
- CEMIP | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.814); catalogued as COSV55001081; called by muse, mutect2, varscan2
- CEP192 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as COSV58071273; called by muse, mutect2, varscan2
- CERS3 | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV52575386; called by muse, mutect2, varscan2
- CFAP43 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as COSV53381849; called by muse, mutect2, varscan2
- CFAP54 | c.7003G>A p.D2335N | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV100733407; called by muse, mutect2, varscan2
- CHAF1A | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV56674615; called by muse, mutect2, varscan2
- CHD5 | c.3725C>T p.P1242L | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.354); catalogued as rs772821101, COSV99314681, COSV99315317; called by muse, varscan2
- CHD5 | c.3724C>T p.P1242S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.269); catalogued as COSV99315322; called by muse, varscan2
- CLASP2 | c.3329C>T p.S1110F (on ENST00000359576; = p.S1109F on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV56286958; called by muse, mutect2, varscan2
- CLDN4 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs372116449; called by muse, mutect2, varscan2
- CLEC4E | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV55227534; called by muse, mutect2, varscan2
- CLIP4 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60753250; called by muse, mutect2, varscan2
- CNTN2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as rs966267940, COSV59348298; called by muse, mutect2
- CNTROB | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV66609579; called by muse, mutect2, varscan2
- COL13A1 | c.1784G>A p.G595E (on ENST00000398978 / NM_001130103.2; = p.G523E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62575890; called by muse, mutect2, varscan2
- COL22A1 | c.4042G>A p.G1348R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57363282; called by muse, mutect2, varscan2
- COL4A3 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as rs1220487318, COSV67421040; called by muse, mutect2, varscan2
- COL6A6 | c.4345G>A p.G1449R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62032506; called by muse, mutect2, varscan2
- COL6A6 | c.4346G>A p.G1449E | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62018557; called by muse, mutect2, varscan2
- CPT1B | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs531926033, COSV56415887; called by muse, mutect2, varscan2
- CRAMP1 | c.2471A>G p.N824S | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772436155, COSV51966574; called by muse, mutect2, varscan2
- CRYAB | c.72T>G p.F24L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as COSV57053017; called by mutect2, varscan2
- CSF2RA | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 156/274 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs757087323, CM116797, COSV62624262; called by muse, mutect2, varscan2
- CSMD1 | c.4418C>T p.P1473L (on ENST00000520002; = p.P1472L on NM_033225.6) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770896492, COSV59292365, COSV59391451; called by muse, mutect2, varscan2
- CSMD3 | c.9898G>A p.G3300R (on ENST00000297405 / NM_001363185.1; = p.G3131R on NM_052900.3) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52335055; called by muse, mutect2, varscan2
- CSMD3 | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV52165637, COSV52307532; called by muse, mutect2, varscan2
- CTAGE1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs759002167, COSV66945243; called by muse, mutect2, varscan2
- CTRC | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65622164; called by muse, mutect2, varscan2
- CYP20A1 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV61910376, COSV61910501; called by muse, mutect2, varscan2
- CYP2A6 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1425619591, COSV56537510; called by muse, mutect2, varscan2
- CYP2A7 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV52507054; called by muse, mutect2, varscan2
- CYP4B1 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as COSV54726581; called by muse, mutect2, varscan2
- CYP4F3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs1164971245, COSV55414035; called by muse, mutect2, varscan2
- CYTIP | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV51636469; called by muse, mutect2, varscan2
- DCAF5 | c.1367A>T p.Y456F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100432879; called by muse, mutect2, varscan2
- DCANP1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs376193776; called by muse, mutect2
- DCC | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV59092842; called by muse, mutect2, varscan2
- DCUN1D3 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60955064; called by muse, mutect2, varscan2
- DDRGK1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs780030928, COSV100621549; called by muse, varscan2
- DENND4A | c.3593C>T p.P1198L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1555417420, COSV71267133; called by muse, mutect2
- DHX58 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs782671059, COSV52428510; called by muse, mutect2, varscan2
- DIO2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70445800; called by muse, mutect2, varscan2
- DISP3 | c.3103-1G>A p.X1035_splice | Splice Site (SNP) | VAF 112/185 reads (61%) | catalogued as COSV53838656; called by muse, mutect2, varscan2
- DMBT1 | c.5546C>T p.P1849L (on ENST00000338354 / NM_001377530.1; = p.P1092L on NM_004406.3) | Missense Mutation (SNP) | VAF 80/95 reads (84%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV57565201; called by muse, mutect2, varscan2
- DNAH3 | c.5959G>A p.D1987N | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54527448; called by muse, mutect2, varscan2
- DNAH3 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV54556271; called by muse, mutect2, varscan2
- DNAH5 | c.2780C>T p.S927L | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54255706; called by muse, mutect2, varscan2
- DNAH7 | c.5378C>T p.S1793L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs370957269; called by muse, mutect2, varscan2
- DNAJC6 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV54782525; called by muse, mutect2, varscan2
- DOP1A | c.7180G>T p.E2394* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV52286232; called by muse, mutect2, varscan2
- DOP1B | c.4274A>C p.N1425T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV67696652; called by muse, mutect2, varscan2
- DPYSL5 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 119/176 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56516776; called by muse, mutect2, varscan2
- DSCAM | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758563795, COSV68033952, COSV68037545; called by muse, mutect2, varscan2
- DST | c.2882A>G p.N961S (on ENST00000361203 / NM_001374722.1; = p.N635S on NM_001723.6) | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV55043337; called by muse, mutect2, varscan2
- EFCAB3 | c.681G>A p.K227= | Splice Region (SNP) | VAF 13/22 reads (59%) | catalogued as COSV59505300; called by muse, mutect2, varscan2
- EFCAB6 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV53073811; called by muse, mutect2
- EN2 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 65/188 reads (35%) | catalogued as rs997306287, COSV52084240; called by muse, varscan2
- ENPP5 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV57910196; called by muse, mutect2, varscan2
- EPHA3 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60721610; called by muse, mutect2, varscan2
- ERAP2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65941540; called by muse, mutect2, varscan2
- ERICH6 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55803638; called by muse, mutect2, varscan2
- F2RL1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 232/535 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV56997042; called by muse, mutect2, varscan2
- FAM209B | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs140276541, COSV100990998, COSV64915329; called by muse, mutect2, varscan2
- FAM241B | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs770392905, COSV64768894; called by muse, mutect2, varscan2
- FAM47A | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as COSV60500180; called by muse, mutect2, varscan2
- FAM83E | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV54371989; called by muse, mutect2, varscan2
- FAM90A1 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.97); catalogued as COSV56715226; called by muse, mutect2, varscan2
- FANCC | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1368374192, COSV56668057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.6295T>G p.L2099V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.228); catalogued as COSV55830831; called by muse, mutect2, varscan2
- FAT3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); catalogued as rs377604683; called by muse, mutect2, varscan2
- FAT3 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as COSV53180838; called by muse, varscan2
- FBXO40 | c.6G>A p.G2= | Splice Region (SNP) | VAF 37/115 reads (32%) | catalogued as rs771915884, COSV57527170, COSV57528268; called by muse, mutect2, varscan2
- FCRL1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs777013547, COSV63827808; called by muse, mutect2, varscan2
- FCRL5 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV62511305, COSV62514240; called by muse, varscan2
- FCRLA | c.430C>T p.P144S (on ENST00000367959; = p.P121S on NM_032738.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.763); catalogued as rs763531432, COSV52685605; called by muse, mutect2
- FFAR2 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV55833454; called by muse, mutect2, varscan2
- FILIP1 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780705551, COSV52741845; called by muse, mutect2, varscan2
- FKBP6 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782776540, COSV52723525; called by muse, mutect2, varscan2
- FLNB | c.7310G>A p.G2437E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55897763; called by muse, mutect2, varscan2
- FRY | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV66574993; called by muse, mutect2, varscan2
- FRY | c.8728G>C p.E2910Q | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66511852; called by muse, mutect2, varscan2
- FSHR | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.17); catalogued as COSV100436480, COSV58620693; called by muse, mutect2, varscan2
- FYCO1 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 82/152 reads (54%) | catalogued as rs1255035103, COSV56120367; called by muse, mutect2, varscan2
- GDPD2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV65534555; called by muse, mutect2, varscan2
- GIMAP5 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57530569; called by muse, mutect2, varscan2
- GIPC3 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs768692696, COSV59260993; called by muse, mutect2, varscan2
- GLCCI1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.202); catalogued as COSV56205643; called by muse, mutect2, varscan2
- GNA11 | c.607A>T p.M203L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs766426049, COSV50056502; called by muse, mutect2, varscan2
- GOLT1B | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 30/53 reads (57%) | catalogued as COSV99982142; called by muse, mutect2, varscan2
- GPR101 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV53240612; called by muse, mutect2, varscan2
- GPRASP1 | c.1776G>A p.M592I | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV64356594; called by muse, mutect2, varscan2
- GRIA1 | c.2271-1G>A p.X757_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99602714; called by muse, mutect2, varscan2
- GRIA3 | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 54/189 reads (29%) | catalogued as COSV52082140, COSV99991524; called by muse, mutect2, varscan2
- GRIN2A | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV58019918; called by muse, mutect2, varscan2
- GRM3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64469390; called by muse, mutect2, varscan2
- GRM8 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); catalogued as COSV58807935; called by muse, mutect2, varscan2
- HAVCR2 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs758285555, COSV57154987; called by muse, mutect2, varscan2
- HCFC1 | c.6101G>A p.G2034D | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100130029; called by muse, mutect2, varscan2
- HCFC1 | c.6100G>A p.G2034S | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); catalogued as COSV100130030; called by muse, mutect2, varscan2
- HIF1A | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60188914; called by muse, mutect2, varscan2
- HMCN1 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54906237; called by muse, mutect2, varscan2
- HMGCS2 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV101024749, COSV65569512; called by muse, mutect2, varscan2
- HRG | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as COSV51648599; called by muse, mutect2, varscan2
- HSD11B1 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54827054; called by muse, mutect2, varscan2
- HSD3B7 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368430248; called by muse, mutect2, varscan2
- HUWE1 | c.6101C>T p.S2034L | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV53366110; called by muse, mutect2, varscan2
- HYDIN | c.3766G>A p.D1256N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs763669224, COSV66832183; called by muse, mutect2, varscan2
- HYDIN | c.953C>G p.T318S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs1409909598; called by mutect2, varscan2
- HYOU1 | c.2930C>T p.P977L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV101345698; called by muse, mutect2, varscan2
- HYOU1 | c.2929C>T p.P977S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101345700; called by muse, mutect2, varscan2
- IGFL1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.051); catalogued as COSV71443714; called by muse, mutect2, varscan2
- IGFL2 | c.139C>G p.P47A (on ENST00000377693 / NM_001135113.2; = p.P58A on NM_001002915.2) | Missense Mutation (SNP) | VAF 151/290 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66617559; called by muse, mutect2, varscan2
- IGSF1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV63840769; called by muse, mutect2, varscan2
- IKBIP | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61082861; called by muse, mutect2, varscan2
- IKZF2 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV59584783; called by muse, mutect2, varscan2
- IL23R | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV61376536; called by muse, mutect2, varscan2
- ILDR1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759748774, COSV56548375; called by muse, mutect2, varscan2
- INHBE | c.781T>A p.W261R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56989249; called by muse, mutect2, varscan2
- INSL3 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100427641; called by muse, mutect2, varscan2
- INSRR | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 50/189 reads (26%) | catalogued as rs201715497, COSV63871157; called by muse, mutect2, varscan2
- ITGA10 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.536); catalogued as rs774263372, COSV65199422; called by muse, mutect2, varscan2
- ITGB1BP2 | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52140665; called by muse, varscan2
- ITGB4 | c.2645C>T p.T882I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs753528501, COSV52333646; called by muse, mutect2, varscan2
- IWS1 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54872254; called by muse, mutect2, varscan2
- JAM2 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs1419323672, COSV57261040; called by muse, mutect2, varscan2
- JMJD1C | c.3025C>T p.Q1009* | Nonsense Mutation (SNP) | VAF 75/89 reads (84%) | catalogued as COSV59518091; called by muse, mutect2, varscan2
- KCNB2 | c.2683C>T p.H895Y | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs866710129, COSV73049516; called by muse, mutect2, varscan2
- KCNH5 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs757261683, COSV59759990; called by muse, mutect2, varscan2
- KCNK13 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV99965964; called by muse, mutect2, varscan2
- KCNK13 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99965965; called by muse, mutect2, varscan2
- KCNMA1 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 80/103 reads (78%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV54292420; called by muse, mutect2, varscan2
- KCNQ2 | c.1899G>A p.M633I (on ENST00000359125 / NM_172107.4; = p.M605I on NM_004518.6) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.989); catalogued as COSV60555319; called by muse, mutect2, varscan2
- KCNQ3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66483195; called by muse, mutect2, varscan2
- KCNQ4 | c.1614-1G>A p.X538_splice | Splice Site (SNP) | VAF 46/81 reads (57%) | catalogued as COSV100714391, COSV61276058; called by muse, mutect2, varscan2
- KIAA1109 | c.5261C>T p.S1754F | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52695406; called by muse, mutect2, varscan2
- KIAA1210 | c.2818G>A p.D940N | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs199658448, COSV68179033; called by muse, mutect2, varscan2
- KIAA1217 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56821434; called by muse, mutect2, varscan2
- KIF4B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV101469235, COSV70531830; called by muse, mutect2, varscan2
- KIF6 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV54696807; called by muse, mutect2, varscan2
- KIR3DL1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 100/152 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV58496626; called by muse, mutect2, varscan2
- KLHL38 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58089433; called by muse, mutect2, varscan2
- KLK3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV58098611; called by muse, mutect2, varscan2
- KMT2E | c.5155C>T p.P1719S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs777332579, COSV57580589; called by muse, mutect2, varscan2
- KRT2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs757450461, COSV59011176, COSV59012049; called by muse, mutect2, varscan2
- KRT20 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51426372; called by muse, mutect2, varscan2
- KRT78 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV58853984; called by muse, mutect2, varscan2
- KRT9 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV55855645; called by muse, mutect2, varscan2
- KRTAP10-1 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555916981, COSV59982020; called by muse, mutect2, varscan2
- KSR2 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV56684923; called by mutect2, varscan2
- LAMA2 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70356170; called by muse, mutect2, varscan2
- LAMB4 | c.2873G>A p.G958E | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV52732386; called by muse, mutect2, varscan2
- LAMC2 | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99918032; called by muse, mutect2, varscan2
- LAMC2 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV99918033; called by muse, mutect2, varscan2
- LDLRAD4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63343667; called by muse, mutect2, varscan2
- LIMCH1 | c.691A>T p.S231C | Missense Mutation (SNP) | VAF 186/230 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58298535; called by muse, mutect2, varscan2
- LOXL4 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.96); catalogued as COSV53259623; called by muse, mutect2, varscan2
- LRGUK | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV53644705; called by muse, mutect2, varscan2
- LRP10 | c.2096C>G p.P699R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV62078990; called by muse, mutect2
- LRP1B | c.10474C>T p.H3492Y | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.808); catalogued as COSV67279889; called by muse, mutect2, varscan2
- LRRIQ4 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1413452358, COSV61618740; called by muse, mutect2, varscan2
- LUZP2 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867125788, COSV61219728; called by muse, mutect2, varscan2
- MAGEB6B | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs369170963; called by muse, mutect2, varscan2
- MAGEC1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 128/249 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as COSV99594673; called by muse, varscan2
- MAGI2 | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62646882, COSV62671388; called by muse, mutect2, varscan2
- MAP3K21 | c.2596C>A p.P866T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100786176; called by muse, mutect2, varscan2
- MAP3K21 | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs760993530, COSV100786116, COSV64042655; called by muse, mutect2, varscan2
- MAP4K1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99943208; called by muse, mutect2, varscan2
- MARCHF11 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60135718; called by muse, mutect2, varscan2
- MATN4 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | PolyPhen benign (0.006); catalogued as COSV59216063; called by muse, mutect2, varscan2
- MCM4 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs755898364, COSV100031916; called by muse, mutect2, varscan2
- MCTP1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs773278512, COSV56503881; called by muse, mutect2, varscan2
- MED1 | c.2964A>C p.L988F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.082); catalogued as COSV56127417, COSV56128907; called by muse, mutect2, varscan2
- MEP1B | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52500339; called by muse, mutect2, varscan2
- MET | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV59257569, COSV59270205; called by muse, mutect2, varscan2
- MINK1 | c.693C>T p.P231= | Splice Region (SNP) | VAF 18/54 reads (33%) | catalogued as COSV61793852; called by muse, mutect2, varscan2
- MLXIPL | c.2414A>G p.Y805C | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV57670771; called by muse, mutect2, varscan2
- MMP15 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54681806; called by muse, mutect2, varscan2
- MORC2 | c.1368C>T p.I456= (on ENST00000397641 / NM_001303256.3; = p.I394= on NM_014941.3) | Splice Region (SNP) | VAF 53/106 reads (50%) | catalogued as rs777612473, COSV53203192; called by muse, mutect2, varscan2
- MROH2B | c.3614C>T p.S1205L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101270952, COSV68188380; called by muse, mutect2, varscan2
- MROH7 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV100273930, COSV59878621; called by muse, mutect2, varscan2
- MRPL58 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as rs1262713189, COSV56900784; called by muse, mutect2, varscan2
- MSANTD2 | c.1552G>A p.D518N (on ENST00000374979 / NM_001308027.2; = p.D466N on NM_024631.4) | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.272); catalogued as COSV53448753, COSV53451521; called by muse, mutect2, varscan2
- MTMR3 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV60309286; called by muse, mutect2, varscan2
- MTUS1 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV50599375; called by muse, mutect2, varscan2
- MTUS2 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV70923657; called by muse, mutect2, varscan2
- MUC15 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs779278615, COSV99846480; called by muse, mutect2, varscan2
- MUC16 | c.18261G>A p.M6087I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.026); catalogued as COSV67479636, COSV67497893; called by muse, mutect2, varscan2
- MUC16 | c.12482C>T p.S4161F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); catalogued as rs1442590851, COSV67443051; called by muse, mutect2, varscan2
- MUC16 | c.10198C>T p.P3400S | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV67497909; called by muse, mutect2, varscan2
- MUC5B | c.14606C>T p.S4869F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV71596010; called by muse, mutect2, varscan2
- MUSK | c.2593G>A p.G865R | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV51898174; called by muse, varscan2
- MYB | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs749820799, COSV57202284; called by muse, mutect2, varscan2
- MYH2 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99821104; called by muse, mutect2, varscan2
- MYH4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs866666239, COSV55127367; called by muse, mutect2, varscan2
- MYH8 | c.4124G>A p.R1375K | Missense Mutation (SNP) | VAF 133/328 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV67973516; called by muse, mutect2, varscan2
- MYO1A | c.2190G>A p.W730* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as COSV55657771; called by muse, mutect2, varscan2
- MYO1B | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58429365; called by muse, mutect2, varscan2
- MYO7B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371035844; called by muse, varscan2
- MYOCD | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs751148214, COSV58497739; called by muse, mutect2, varscan2
- MYOCD | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58513333; called by muse, mutect2, varscan2
- MYPN | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.3); PolyPhen benign (0.433); catalogued as COSV62740384; called by muse, mutect2, varscan2
- NCAN | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV53060075, COSV99386929; called by muse, mutect2, varscan2
- NCOA1 | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV56054087; called by muse, mutect2, varscan2
- NEBL | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as COSV65806238; called by muse, mutect2, varscan2
- NETO1 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55016164; called by muse, mutect2, varscan2
- NFASC | c.746C>T p.P249L (on ENST00000339876 / NM_001378329.1; = p.P260L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100366029; called by muse, mutect2, varscan2
- NLGN1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV64348432; called by muse, mutect2, varscan2
- NLGN4X | c.699G>A p.W233* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99324285; called by muse, mutect2, varscan2
- NLGN4X | c.698G>A p.W233* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99324289; called by muse, mutect2, varscan2
- NLRC4 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV61595100; called by muse, mutect2, varscan2
- NLRP1 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747487022, COSV52561169; called by muse, mutect2, varscan2
- NLRP7 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 253/484 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as rs1483043148, COSV60182672; called by muse, mutect2, varscan2
- NMS | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 120/186 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as COSV100966542, COSV65259381; called by muse, mutect2, varscan2
- NOS1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80348085, COSV57606077; called by muse, mutect2, varscan2
- NOS1AP | c.596-1G>A p.X199_splice | Splice Site (SNP) | VAF 60/158 reads (38%) | catalogued as COSV62640680; called by muse, mutect2, varscan2
- NRDE2 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV62964954; called by muse, varscan2
- NRROS | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.716); catalogued as COSV100145655; called by muse, mutect2
- NSUN4 | c.94-2A>T p.X32_splice | Splice Site (SNP) | VAF 60/105 reads (57%) | catalogued as COSV61063998; called by muse, mutect2, varscan2
- NTN5 | c.1024+1G>T p.X342_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | catalogued as COSV54308897; called by muse, mutect2, varscan2
- NUBP1 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368752350; called by mutect2, varscan2
- NUTM1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.203); catalogued as COSV100412656; called by muse, mutect2, varscan2
- NUTM1 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as rs771843670, COSV100412657; called by muse, mutect2, varscan2
- OR10G8 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV70909535; called by muse, mutect2, varscan2
- OR10J1 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as COSV71129832; called by muse, mutect2, varscan2
- OR10J1 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV71128497; called by muse, mutect2, varscan2
- OR10X1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100936633, COSV63766869; called by muse, mutect2, varscan2
- OR11H4 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV59561017; called by muse, mutect2, varscan2
- OR13C9 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV52243229; called by muse, mutect2, varscan2
- OR1S1 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58708765; called by muse, mutect2, varscan2
- OR2A25 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs781251490, COSV68716866, COSV68716922; called by muse, mutect2, varscan2
- OR2G6 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 24/149 reads (16%) | catalogued as COSV58575478, COSV58575543; called by muse, mutect2, varscan2
- OR2J2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1168744281, COSV65847663; called by muse, mutect2
- OR2L3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 108/196 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV63456503; called by muse, varscan2
- OR2T1 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs750750938, COSV63543017; called by muse, mutect2, varscan2
- OR2T5 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV63540970; called by muse, mutect2, varscan2
- OR2T6 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV63216835, COSV63217145; called by muse, mutect2, varscan2
- OR4F15 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV59970484, COSV99046068; called by muse, mutect2, varscan2
- OR4F6 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV61027373, COSV61027724; called by muse, mutect2, varscan2
- OR51B6 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.158); catalogued as COSV66513189; called by muse, varscan2
- OR51V1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV58316528, COSV58316842; called by muse, mutect2, varscan2
- OR52A1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV61093428; called by muse, mutect2, varscan2
- OR52E4 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57624616, COSV57626493; called by muse, varscan2
- OR52H1 | c.577G>A p.D193N (on ENST00000322653; = p.D199N on NM_001005289.1) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV59506350; called by muse, mutect2, varscan2
- OR5K4 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as COSV61584429; called by muse, mutect2, varscan2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- OR8G2P | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs758366735; called by muse, mutect2, varscan2
- OR8S1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59600974; called by muse, mutect2, varscan2
- ORC4 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51577460; called by muse, mutect2
- OSBPL6 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51931769; called by muse, mutect2, varscan2
- OTOF | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); catalogued as COSV99719205; called by muse, mutect2, varscan2
- OTUD4 | c.1667C>T p.P556L (on ENST00000447906 / NM_001366057.1; = p.P491L on NM_001102653.1) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs760455482, COSV71382359; called by muse, mutect2, varscan2
- P2RY8 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV67178406; called by muse, mutect2, varscan2
- PCDH11X | c.3185A>C p.Q1062P | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV53509292; called by muse, mutect2, varscan2
- PCDHB15 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782786455, COSV51426536, COSV99178837; called by muse, mutect2, varscan2
- PCDHGA6 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV54044354; called by muse, mutect2, varscan2
- PCDHGA6 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); catalogued as COSV54044374; called by muse, mutect2, varscan2
- PCLO | c.11084C>T p.A3695V | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs774055010, COSV61671492; called by muse, mutect2, varscan2
- PCLO | c.6988C>T p.R2330* | Nonsense Mutation (SNP) | VAF 84/212 reads (40%) | catalogued as COSV61671534; called by muse, mutect2, varscan2
- PCLO | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 54/118 reads (46%) | catalogued as COSV61671558; called by muse, mutect2, varscan2
- PCNX2 | c.5583G>A p.W1861* | Nonsense Mutation (SNP) | VAF 26/47 reads (55%) | catalogued as COSV50797291, COSV50918529; called by muse, mutect2, varscan2
- PCSK6 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59345402; called by muse, mutect2, varscan2
- PDE10A | c.2268-1G>A p.X756_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100605967; called by muse, mutect2
- PDPR | c.2396C>T p.T799I | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV55357399; called by muse, mutect2, varscan2
- PDZD2 | c.7348G>A p.G2450R | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56874456; called by muse, mutect2, varscan2
- PEAR1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52776288; called by muse, mutect2, varscan2
- PEG3 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.382); catalogued as COSV55649454; called by muse, mutect2, varscan2
- PGK2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59165802; called by muse, mutect2, varscan2
- PI16 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV65321498; called by muse, mutect2, varscan2
- PIGV | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV50309590; called by muse, mutect2, varscan2
- PIGV | c.1122C>A p.F374L | Missense Mutation (SNP) | VAF 80/135 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV50310039; called by muse, mutect2, varscan2
- PIP | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV52121843; called by muse, mutect2, varscan2
- PITPNM1 | c.1627T>C p.Y543H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62710112; called by muse, mutect2, varscan2
- PITPNM2 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs267603358, COSV54901116, COSV54907091; called by muse, mutect2, varscan2
- PKHD1 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61896797; called by muse, mutect2, varscan2
- PKP2 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV50751685; called by muse, mutect2, varscan2
- PLCB1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1308729547, COSV62060690; called by muse, mutect2, varscan2
- PLCB1 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62070921; called by muse, mutect2, varscan2
- PLCB2 | c.3358C>T p.Q1120* | Nonsense Mutation (SNP) | VAF 35/65 reads (54%) | catalogued as COSV99542769; called by muse, mutect2, varscan2
- PLCB2 | c.3357C>T p.F1119= | Splice Region (SNP) | VAF 33/62 reads (53%) | catalogued as COSV99542771; called by muse, mutect2, varscan2
- PLCB4 | c.3509G>A p.R1170K (on ENST00000278655 / NM_182797.3; = p.Q1182= on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.745); catalogued as COSV53820334; called by muse, mutect2, varscan2
- PLEKHM1 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV69599514; called by muse, mutect2, varscan2
- PLG | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as rs777552429, COSV51986840; called by muse, mutect2, varscan2
- PLPPR4 | c.903T>A p.Y301* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as COSV64567861; called by muse, mutect2, varscan2
- PLXNB1 | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56494687; called by muse, mutect2, varscan2
- POLR1F | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55999824; called by muse, mutect2, varscan2
- POLR2J | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 102/143 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1391631592, COSV53001157; called by muse, mutect2, varscan2
- PORCN | c.781C>T p.L261F (on ENST00000326194 / NM_203475.3; = p.L250F on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV58227324; called by muse, mutect2, varscan2
- POTEE | c.2834G>A p.G945D | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs754472471, COSV58246293; called by muse, varscan2
- POU2F2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV60767046; called by muse, mutect2, varscan2
- PPIL1 | c.442A>G p.N148D | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65473118; called by muse, mutect2, varscan2
- PPP1R3A | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52894150; called by muse, mutect2, varscan2
- PRAMEF15 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as rs1553166915; called by muse, mutect2, varscan2
- PRAMEF20 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 110/387 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as rs1200392559; called by muse, mutect2, varscan2
- PRC1 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 357/763 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV62696809; called by muse, mutect2, varscan2
- PRDM9 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV57002697; called by muse, mutect2, varscan2
- PRPF19 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57129452; called by muse, mutect2, varscan2
- PRRC2A | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63225082; called by muse, mutect2, varscan2
- PRSS22 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50721374, COSV50724446; called by muse, mutect2, varscan2
- PRX | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as COSV99398120; called by muse, varscan2
- PTPN1 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV50407117; called by muse, mutect2
- PTPN9 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60723100; called by muse, mutect2, varscan2
- PTPRB | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV51741430; called by muse, mutect2, varscan2
- PTPRD | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61985664; called by muse, mutect2, varscan2
- PTPRF | c.4109C>T p.S1370L | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV63449339; called by muse, mutect2, varscan2
- PTPRK | c.3621G>A p.M1207I (on ENST00000368215 / NM_001291984.2; = p.M1208I on NM_002844.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV63908368; called by muse, mutect2, varscan2
- PTPRN2 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 50/91 reads (55%) | catalogued as rs142009346, COSV67039058; called by muse, mutect2, varscan2
- PTPRT | c.3988C>T p.R1330C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1318044562, COSV61965535; called by muse, mutect2, varscan2
- PZP | c.4217A>C p.E1406A | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as COSV54371455; called by muse, mutect2, varscan2
- RAB6C | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV101308575, COSV69339295; called by muse, mutect2, varscan2
- RADIL | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV101271637; called by muse, mutect2, varscan2
- RALBP1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50039905; called by muse, mutect2, varscan2
- RANBP2 | c.5606C>T p.S1869L | Missense Mutation (SNP) | VAF 136/214 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51700727, COSV51709548; called by muse, mutect2, varscan2
- RASD2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs143019718; called by muse, varscan2
- RBM6 | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99806043; called by muse, mutect2, varscan2
- RBMXL2 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.325); catalogued as rs757799205, COSV60979311, COSV60981788; called by muse, mutect2, varscan2
- RC3H1 | c.294A>C p.E98D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV51220774; called by muse, mutect2, varscan2
- RCVRN | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56841528, COSV99874084; called by muse, mutect2, varscan2
- RELN | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.952); catalogued as COSV59036600; called by muse, mutect2, varscan2
- RFX4 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63507650; called by muse, mutect2, varscan2
- RGS16 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359732978, COSV62376027; called by muse, mutect2
- RNLS | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 24/34 reads (71%) | catalogued as rs1363362756, COSV59292137; called by muse, mutect2, varscan2
- RNLS | c.863G>A p.W288* | Nonsense Mutation (SNP) | VAF 26/36 reads (72%) | catalogued as COSV100076658, COSV100077193; called by muse, mutect2, varscan2
- ROS1 | c.2814G>A p.G938= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as COSV63851428; called by muse, mutect2, varscan2
- RPL18 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV50032487; called by muse, mutect2, varscan2
- RSPH6A | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55575923; called by muse, mutect2, varscan2
- RSPO1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs201204537, COSV100740567; called by muse, varscan2
- RTN4 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1465913217, COSV100464097; called by muse, mutect2
- RYR1 | c.8080G>A p.E2694K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV62108358; called by muse, mutect2, varscan2
- SACS | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs376187491, COSV66547458; called by muse, mutect2, varscan2
- SAMD7 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV59421889; called by muse, mutect2, varscan2
- SCN11A | c.2474G>A p.G825E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs1192118831, COSV56579368; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.3947G>A p.R1316Q (on ENST00000333535 / NM_198056.3; = p.R1315Q on NM_000335.5) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs765907469, CM143810, COSV100346967, COSV61139531; called by muse, mutect2, varscan2
- SCOC | c.184C>T p.H62Y (on ENST00000608372; = p.H25Y on NM_032547.3) | Missense Mutation (SNP) | VAF 68/91 reads (75%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV58393990; called by muse, mutect2, varscan2
- SCRN3 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 97/143 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1184246011, COSV55810179; called by muse, mutect2, varscan2
- SCYL3 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV63047884; called by muse, mutect2, varscan2
- SEMA3E | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV57110885; called by muse, mutect2, varscan2
- SERINC3 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV54858705; called by muse, mutect2, varscan2
- SERPINB2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV55095253; called by muse, mutect2, varscan2
- SFTPA2 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 121/156 reads (78%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs777910370, COSV64882906; called by muse, mutect2, varscan2
- SI | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52303537; called by muse, mutect2, varscan2
- SIRPD | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV67547320; called by muse, mutect2
- SIT1 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 54/66 reads (82%) | catalogued as COSV52400459; called by muse, mutect2, varscan2
- SKAP1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV61153334; called by muse, mutect2, varscan2
- SLC12A8 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs575976593, COSV58867175, COSV58870282; called by muse, mutect2, varscan2
- SLC22A3 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV51717736; called by muse, mutect2, varscan2
- SLC26A2 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV53826999; called by muse, mutect2, varscan2
- SLC35D3 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as rs1351029794, COSV59378447; called by muse, mutect2, varscan2
- SLC38A11 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58056377; called by muse, mutect2
- SLC45A4 | c.2150C>T p.P717L (on ENST00000517878 / NM_001286646.2; = p.P666L on NM_001080431.2) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99200814; called by muse, mutect2, varscan2
- SLC7A1 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV66332027; called by muse, mutect2, varscan2
- SLC7A13 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs1166574349, COSV52537202, COSV52537712; called by muse, mutect2, varscan2
- SLC8B1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV52530874; called by muse, mutect2, varscan2
- SLC9A2 | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs41280603, COSV52138535; called by muse, mutect2, varscan2
- SLCO2B1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV56940068; called by muse, mutect2, varscan2
- SLCO5A1 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV52669282; called by muse, mutect2, varscan2
- SMARCA1 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV64414082; called by muse, mutect2, varscan2
- SMG7 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV61634690; called by muse, mutect2, varscan2
- SORL1 | c.6603G>A p.M2201I | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV52750214; called by muse, mutect2, varscan2
- SOX3 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs781740592, COSV100983776, COSV65168775; called by mutect2, varscan2
- SOX6 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100323427; called by muse, mutect2
- SOX6 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57059275; called by muse, mutect2, varscan2
- SPANXC | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs782637722, COSV62842015; called by muse, mutect2
- SPATA20 | c.1911C>T p.D637= (on ENST00000356488 / NM_001258372.1; = p.D653= on NM_022827.4) | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as COSV50070826; called by muse, mutect2, varscan2
- SPEN | c.6599C>T p.P2200L | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV65367973; called by muse, mutect2, varscan2
- SPHKAP | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV60879299; called by muse, mutect2, varscan2
- SPHKAP | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV60892859; called by muse, mutect2, varscan2
- SRPK3 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54209042, COSV99473118; called by muse, mutect2, varscan2
- SRRM1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV60480976; called by muse, mutect2, varscan2
- STAP2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55699214; called by muse, mutect2, varscan2
- STRIP1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100874003; called by muse, mutect2, varscan2
- STYXL2 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54807195, COSV54810599; called by muse, mutect2, varscan2
- SULT1A2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.078); catalogued as rs1289180318, COSV57681459; called by muse, mutect2, varscan2
- SULT4A1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99970703, COSV99970729; called by muse, mutect2, varscan2
- SUN2 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99325892; called by muse, mutect2, varscan2
- SUN2 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99325895; called by muse, mutect2, varscan2
- SUPT3H | c.946-1G>A p.X316_splice (on ENST00000371460 / NM_181356.3; = p.X305_splice on NM_003599.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 41/88 reads (47%) | catalogued as COSV100178429; called by muse, mutect2, varscan2
- SYNE1 | c.19667C>T p.S6556F (on ENST00000367255 / NM_182961.4; = p.S6485F on NM_033071.3) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.723); catalogued as COSV99581961; called by muse, mutect2, varscan2
- SYNE1 | c.1282G>A p.E428K (on ENST00000367255 / NM_182961.4; = p.E435K on NM_033071.3) | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV54945368; called by muse, mutect2, varscan2
- SYT4 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs868800562, COSV54904564; called by muse, mutect2, varscan2
- TACC2 | c.5759C>T p.S1920L | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369648685; called by muse, mutect2, varscan2
- TAF1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.383); catalogued as COSV52126800; called by muse, mutect2, varscan2
- TAF1L | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1299548601, COSV54266968, COSV54267258; called by muse, mutect2, varscan2
- TAS2R60 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as COSV60332281; called by muse, mutect2, varscan2
- TBC1D24 | c.1364C>T p.P455L (on ENST00000646147 / NM_001199107.2; = p.P449L on NM_020705.3) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV99565336; called by muse, mutect2, varscan2
- TBC1D7 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58245136; called by muse, mutect2, varscan2
- TECTB | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT tolerated (0.49); PolyPhen benign (0.119); catalogued as rs142157041; called by muse, mutect2, varscan2
- TENM1 | c.4555C>T p.R1519C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64431715; called by muse, mutect2, varscan2
- TET3 | c.2989C>T p.R997W | Missense Mutation (SNP) | VAF 175/233 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69641568; called by muse, mutect2, varscan2
- TFDP3 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as COSV59538835; called by muse, mutect2, varscan2
- TGM7 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV71773206; called by muse, mutect2, varscan2
- TGOLN2 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 139/783 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99965168; called by muse, mutect2, varscan2
- TGOLN2 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 139/779 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.124); catalogued as COSV56405669; called by muse, mutect2, varscan2
- THAP12 | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52613424; called by muse, mutect2, varscan2
- THRB | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV62842595; called by muse, mutect2, varscan2
- THSD4 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs777553782, COSV55986344; called by muse, mutect2, varscan2
- THSD7A | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1273985579, COSV70273780; called by muse, mutect2, varscan2
- THSD7B | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775249555, COSV55674045, COSV55742842; called by muse, mutect2, varscan2
- TIAM2 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as COSV51639343; called by muse, mutect2, varscan2
- TJP1 | c.3929C>T p.P1310L | Missense Mutation (SNP) | VAF 151/391 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as rs372973125; called by muse, mutect2, varscan2
- TJP3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195030059, COSV53666021; called by muse, mutect2, varscan2
- TLR8 | c.1492C>T p.P498S (on ENST00000218032 / NM_138636.5; = p.P516S on NM_016610.4) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1485406843, COSV54321194; called by muse, mutect2, varscan2
- TMEM132B | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.732); catalogued as rs867743033, COSV54772403; called by muse, mutect2, varscan2
- TMEM14B | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65356571; called by muse, mutect2, varscan2
- TMEM67 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100020035; called by muse, mutect2, varscan2
- TMEM67 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV100019569; called by muse, mutect2, varscan2
- TNC | c.4643C>T p.S1548F | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV60785188; called by muse, mutect2, varscan2
- TNFRSF25 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1392680715, COSV61069816; called by muse, mutect2, varscan2
- TNN | c.2715G>A p.W905* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as rs1339395949, COSV53437044, COSV53437562; called by muse, mutect2, varscan2
- TOP3A | c.2022G>A p.G674= | Splice Region (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100329347; called by muse, mutect2, varscan2
- TOP3A | c.2022-1G>A p.X674_splice | Splice Site (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100329350; called by muse, mutect2, varscan2
- TOPORS | c.278T>A p.V93E | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV62118416; called by muse, mutect2, varscan2
- TRANK1 | c.7013G>A p.G2338E | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV57155417; called by muse, mutect2, varscan2
- TRBV24-1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); catalogued as rs889749251; called by muse, mutect2, varscan2
- TRHDE | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53868303; called by muse, mutect2, varscan2
- TRIM4 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 120/270 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs544095744, COSV62469872; called by muse, mutect2, varscan2
- TRIP12 | c.4247G>A p.R1416K | Missense Mutation (SNP) | VAF 78/120 reads (65%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.815); catalogued as COSV52273662; called by muse, mutect2, varscan2
- TRIP12 | c.3095C>T p.T1032I | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52273675; called by muse, mutect2, varscan2
- TRIT1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV57550414; called by muse, mutect2, varscan2
- TRO | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.284); catalogued as COSV51508637, COSV51508941; called by muse, mutect2, varscan2
- TRPC5 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749694789, COSV53287947; called by muse, mutect2, varscan2
- TRPV4 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV55686169; called by muse, mutect2
- TRPV6 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV63893978; called by muse, mutect2, varscan2
- TSPOAP1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52119020; called by muse, mutect2, varscan2
- TTLL9 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV60596997; called by muse, mutect2, varscan2
- TTN | c.75220G>A p.V25074I (on ENST00000591111; = p.V17650I on NM_003319.4) | Missense Mutation (SNP) | VAF 26/107 reads (24%) | PolyPhen benign (0); catalogued as COSV100633405; called by muse, mutect2, varscan2
- TTN | c.31025C>T p.P10342L (on ENST00000591111; = p.P9415L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/63 reads (67%) | PolyPhen benign (0); catalogued as rs762289992, COSV60383340; called by muse, mutect2, varscan2
- TTN | c.18607G>A p.E6203K (on ENST00000591111; = p.E5276K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | PolyPhen benign (0.017); catalogued as COSV59914803, COSV60176535; called by muse, mutect2, varscan2
- TTN | c.17482G>A p.E5828K (on ENST00000591111; = p.E4901K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/38 reads (63%) | PolyPhen possibly damaging (0.54); catalogued as rs267599065, COSV60006328; called by muse, mutect2, varscan2
- U2AF2 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as COSV58276593; called by muse, varscan2
- UBE3C | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as rs1288938551, COSV61954566, COSV61955869; called by muse, mutect2, varscan2
- UBL7 | c.1006-1G>A p.X336_splice | Splice Site (SNP) | VAF 44/90 reads (49%) | catalogued as COSV100795479; called by muse, mutect2, varscan2
- UBN2 | c.2119-1G>A p.X707_splice | Splice Site (SNP) | VAF 22/40 reads (55%) | catalogued as COSV56036077; called by muse, mutect2
- UBR2 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65752916; called by muse, mutect2, varscan2
- UGT2B11 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs188477794, COSV71424236; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4330C>T p.L1444F | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54443245; called by muse, mutect2, varscan2
- UIMC1 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV65895297; called by muse, mutect2, varscan2
- UNC79 | c.2534G>A p.G845E (on ENST00000393151 / NM_001346218.2; = p.G668E on NM_020818.5) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs765969402, COSV56376159, COSV56386310, COSV56392104; called by muse, mutect2, varscan2
- UNC79 | c.7076G>A p.G2359E (on ENST00000393151 / NM_001346218.2; = p.G2182E on NM_020818.5) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56414260; called by muse, mutect2, varscan2
- UPF3B | c.1411G>A p.E471K (on ENST00000276201 / NM_080632.3; = p.E458K on NM_023010.3) | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52231501; called by muse, mutect2, varscan2
- USH2A | c.9077C>T p.P3026L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56446774; called by muse, mutect2, varscan2
- USH2A | c.5705G>A p.G1902E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV56352079; called by muse, mutect2, varscan2
- VIRMA | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 168/436 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV99889663; called by muse, mutect2, varscan2
- VPS8 | c.2834C>T p.S945F (on ENST00000625842 / NM_001349294.1; = p.S943F on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV54997647; called by muse, mutect2, varscan2
- VWA3B | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1201753379, COSV68247215; called by muse, mutect2, varscan2
- VWA5A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs201601409, COSV63707493; called by muse, mutect2, varscan2
- VWF | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV54636234; called by muse, mutect2, varscan2
- WDR49 | c.142C>T p.P48S (on ENST00000308378 / NM_001366158.1; = p.P389S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336143503, COSV57718854; called by muse, mutect2
- WDR62 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54340086; called by muse, mutect2
- WDR86 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as COSV57844013; called by muse, mutect2, varscan2
- XAF1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); catalogued as rs1023555687, COSV60973671; called by muse, mutect2, varscan2
- YLPM1 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV53121616; called by muse, mutect2, varscan2
- ZCCHC12 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV59573135; called by muse, mutect2, varscan2
- ZFHX3 | c.5696G>T p.G1899V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV51720026, COSV51738547; called by muse, mutect2, varscan2
- ZFHX3 | c.3026T>G p.V1009G | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV51738560; called by muse, mutect2, varscan2
- ZFP28 | c.2386C>T p.Q796* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | catalogued as COSV56738429; called by muse, mutect2, varscan2
- ZFYVE16 | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV62018271; called by muse, mutect2, varscan2
- ZIK1 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV56737254; called by muse, mutect2, varscan2
- ZNF296 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 231/386 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs761528757, COSV55519764; called by muse, mutect2, varscan2
- ZNF454 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV60770563; called by muse, mutect2, varscan2
- ZNF48 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV60784467; called by muse, mutect2, varscan2
- ZNF532 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60176135; called by muse, mutect2, varscan2
- ZNF599 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV61397638; called by muse, mutect2, varscan2
- ZNF610 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs762894343, COSV58345455, COSV58346895; called by muse, mutect2, varscan2
- ZNF676 | c.1082G>A p.R361K (on ENST00000650058; = p.R329K on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.129); catalogued as COSV101236131, COSV68095181; called by muse, mutect2, varscan2
- ZNF774 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1027899625, COSV62980125; called by muse, mutect2, varscan2
- ZNF816 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54412970; called by muse, mutect2, varscan2
- ZPBP2 | c.125T>G p.I42R (on ENST00000348931 / NM_199321.3; = p.I20R on NM_198844.3) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV62375820; called by muse, mutect2, varscan2
- ZSWIM8 | c.328T>A p.F110I | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV67135142; called by muse, varscan2
- BDH1 | c.1029del p.*344Efs*23 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel
- COL16A1 | c.996_997insCA p.S333Hfs*129 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, varscan2
- FOXD4L4 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by mutect2, varscan2
- GUF1 | c.961_963del p.L321del | In Frame Del (DEL) | VAF 32/35 reads (91%) | called by mutect2, pindel, varscan2
- RADIL | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- RBBP6 | c.3165del p.E1056Nfs*55 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 130/694 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); called by muse, varscan2
- SPATA31A3 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by mutect2, varscan2
- STAG2 | c.589del p.M197Wfs*28 | Frame Shift Del (DEL) | VAF 96/212 reads (45%) | called by mutect2, pindel, varscan2
- TRAV7 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ZCCHC9 | c.755_757delinsCA p.I252Tfs*24 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by pindel, varscan2*
- ZFHX4 | c.2062del p.R688Gfs*37 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- ACADM | c.15C>T p.F5= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV63721417; called by muse, mutect2, varscan2
- ACSL6 | c.726G>A p.G242= (on ENST00000379240; = p.G267= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV57305777; called by muse, mutect2, varscan2
- ADAM28 | c.1233G>A p.G411= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1464767262, COSV56099444; called by muse, mutect2, varscan2
- ADCY7 | c.447C>T p.A149= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs145728675; called by muse, mutect2, varscan2
- ADIPOR2 | c.1011C>T p.F337= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV63947103; called by muse, mutect2
- ALDH1L1 | c.2001G>A p.V667= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as COSV56419918; called by muse, mutect2, varscan2
- AMPD3 | c.279G>A p.Q93= (on ENST00000396553 / NM_001025389.2; = p.Q102= on NM_000480.3) | Silent (SNP) | VAF 78/219 reads (36%) | catalogued as COSV67332750; called by muse, mutect2, varscan2
- ANGPT1 | c.1485T>A p.P495= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV52458638; called by muse, mutect2, varscan2
- ANK1 | c.2226C>T p.A742= | Silent (SNP) | VAF 68/146 reads (47%) | catalogued as COSV55897549; called by muse, mutect2, varscan2
- ANK3 | c.7830G>A p.E2610= | Silent (SNP) | VAF 34/38 reads (89%) | catalogued as rs761590730, COSV55084875; called by muse, mutect2, varscan2
- ANKFN1 | c.342C>T p.F114= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs200633862; called by muse, mutect2, varscan2
- ANKK1 | c.2004G>A p.Q668= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV58274578; called by muse, mutect2, varscan2
- APPBP2 | c.1161G>A p.E387= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as rs1301210948, COSV99319955; called by muse, mutect2, varscan2
- AR | c.1008C>T p.S336= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV65954025; called by muse, mutect2, varscan2
- ARHGEF11 | c.1137C>T p.I379= | Silent (SNP) | VAF 49/122 reads (40%) | catalogued as COSV63815915; called by muse, mutect2, varscan2
- ARHGEF26 | c.2181G>A p.G727= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV62852522; called by muse, mutect2, varscan2
- ARL13A | c.264G>A p.Q88= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV65880378; called by muse, mutect2, varscan2
- ARSH | c.1131G>A p.E377= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs1253000782, COSV66963920; called by muse, mutect2, varscan2
- ART5 | c.369C>T p.L123= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100731656, COSV63365485; called by muse, mutect2, varscan2
- ASAP3 | c.1110G>A p.R370= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV60878379; called by muse, mutect2, varscan2
- ATG2B | c.1089G>A p.E363= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs1232409089, COSV63426063; called by muse, mutect2, varscan2
- ATP1A1 | c.903C>T p.F301= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as COSV55194621; called by muse, mutect2, varscan2
- ATP1A4 | c.495C>T p.I165= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as rs1452120520, COSV63626018, COSV63628465, COSV63628816; called by muse, mutect2, varscan2
- BCAR1 | c.2466C>T p.L822= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV50807409; called by muse, mutect2, varscan2
- BCAR3 | c.480C>T p.P160= | Silent (SNP) | VAF 44/74 reads (59%) | catalogued as COSV53079837; called by muse, mutect2, varscan2
- BPIFC | c.270T>C p.F90= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV55916294; called by muse, mutect2, varscan2
- BRINP2 | c.1914C>T p.F638= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV64178090, COSV64181056; called by muse, mutect2, varscan2
- BTBD11 | c.2295G>A p.E765= (on ENST00000280758 / NM_001018072.2; = p.E302= on NM_001017523.2) | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV99777135; called by muse, mutect2, varscan2
- BUD13 | c.843C>G p.S281= | Silent (SNP) | VAF 142/379 reads (37%) | catalogued as COSV99496810; called by muse, varscan2
- C11orf53 | c.744C>T p.P248= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV54722749; called by muse, mutect2, varscan2
- C14orf93 | c.9C>T p.F3= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV54442776; called by muse, mutect2, varscan2
- CACNA1A | c.5004C>T p.F1668= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100803361; called by muse, mutect2, varscan2
- CACNA1F | c.4572C>T p.N1524= | Silent (SNP) | VAF 61/198 reads (31%) | catalogued as rs1557105900, COSV59907256; called by muse, mutect2, varscan2
- CACNA1F | c.3969C>T p.S1323= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1557106508, COSV59903359; called by muse, mutect2, varscan2
- CAD | c.339C>T p.I113= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV53032514; called by muse, mutect2, varscan2
- CASS4 | c.216G>A p.T72= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs1228212971, COSV64385768; called by muse, varscan2
- CCDC39 | c.2430C>T p.I810= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV56494796; called by muse, mutect2, varscan2
- CCR9 | c.483G>A p.R161= (on ENST00000357632 / NM_031200.3; = p.R149= on NM_006641.4) | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV62940889; called by muse, mutect2, varscan2
- CD1B | c.555C>T p.P185= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as COSV63805310; called by muse, mutect2, varscan2
- CD300C | c.384G>A p.E128= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs752946104, COSV58171597; called by muse, mutect2, varscan2
- CD3E | c.324G>A p.A108= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs1313464574, COSV62345112; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH20 | c.2115C>T p.I705= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV53004159; called by muse, mutect2, varscan2
- CDH4 | c.936G>A p.G312= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as COSV64676902; called by muse, mutect2, varscan2
- CEACAM16 | c.963C>T p.I321= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as rs748040042, COSV69188041; called by muse, mutect2, varscan2
- CELSR2 | c.3486C>T p.D1162= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV54780189; called by muse, mutect2, varscan2
- CHRM3 | c.759G>A p.R253= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs960010296, COSV55097305, COSV55106778; called by muse, mutect2, varscan2
- CHRM3 | c.954G>A p.K318= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs757656529, COSV55106790; called by muse, mutect2, varscan2
- CHRM4 | c.1212C>A p.A404= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV58996011; called by muse, mutect2, varscan2
- CHRNB1 | c.1173C>T p.F391= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV60142035; called by muse, mutect2, varscan2
- CLEC16A | c.3054C>T p.L1018= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs760484528, COSV55491788; called by muse, mutect2, varscan2
- CNDP1 | c.357G>A p.G119= | Silent (SNP) | VAF 103/211 reads (49%) | catalogued as COSV62595564; called by muse, mutect2, varscan2
- CNTN4 | c.2595G>A p.T865= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs112921386; called by muse, mutect2, varscan2
- COL15A1 | c.1965T>G p.G655= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV66649900; called by muse, mutect2, varscan2
- COPS7A | c.792C>T p.L264= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV57527483, COSV57527643; called by muse, mutect2, varscan2
- CPE | c.333G>A p.G111= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as COSV68582300; called by muse, mutect2, varscan2
- CPQ | c.468C>T p.F156= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1237209399, COSV55162497; called by muse, mutect2, varscan2
- CPZ | c.1197G>A p.E399= (on ENST00000360986 / NM_001014447.3; = p.E388= on NM_003652.3) | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV59926504; called by muse, mutect2, varscan2
- CRLF2 | c.630G>A p.Q210= | Silent (SNP) | VAF 110/187 reads (59%) | catalogued as COSV67494355; called by muse, mutect2, varscan2
- CSMD2 | c.2490C>T p.F830= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV53916453; called by muse, mutect2, varscan2
- DCAF5 | c.1368C>T p.Y456= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100432878; called by muse, mutect2, varscan2
- DCLK3 | c.1548C>T p.T516= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as rs750226765, COSV69362382; called by muse, mutect2, varscan2
- DCST2 | c.762C>T p.I254= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV55055072; called by muse, mutect2, varscan2
- DDX24 | c.2287C>T p.L763= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV52574760; called by muse, mutect2, varscan2
- DERL1 | c.555C>T p.F185= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV52366494; called by muse, mutect2, varscan2
- DISP3 | c.903C>T p.I301= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53838641; called by muse, mutect2, varscan2
- DKK4 | c.489G>A p.T163= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs777200031, COSV55182044; called by muse, mutect2, varscan2
- DMD | c.2163G>A p.R721= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55904839; called by muse, mutect2
- DNAH8 | c.1785G>A p.G595= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV59448259; called by muse, mutect2, varscan2
- DNER | c.1191C>T p.I397= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV59177830; called by muse, varscan2
- DNM3 | c.498G>A p.R166= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV62468269; called by muse, mutect2, varscan2
- DOCK3 | c.4521G>A p.L1507= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV56552578; called by muse, mutect2
- DPP6 | c.39G>A p.Q13= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV68062785; called by muse, mutect2, varscan2
- ECEL1 | c.940C>T p.L314= | Silent (SNP) | VAF 64/89 reads (72%) | catalogued as COSV58814469; called by muse, mutect2, varscan2
- EEF1D | c.210C>T p.S70= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV52789211; called by muse, mutect2, varscan2
- EFCAB6 | c.1266G>A p.P422= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs146730740, COSV53073821; called by muse, mutect2, varscan2
- EFEMP1 | c.228G>A p.Q76= | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV62617470; called by muse, mutect2, varscan2
- EGFLAM | c.555C>T p.F185= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs556511806, COSV59297534; called by muse, mutect2, varscan2
- EP400 | c.6678C>T p.L2226= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs748415028, COSV57788049; called by muse, mutect2, varscan2
- EPHA7 | c.2931C>T p.I977= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100993366, COSV65178330, COSV65192948; called by muse, mutect2, varscan2
- EPHA7 | c.1932C>T p.F644= | Silent (SNP) | VAF 52/70 reads (74%) | catalogued as rs759807489, COSV65178824; called by muse, mutect2, varscan2
- ERBB2 | c.1404C>T p.I468= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV54084340; called by muse, mutect2, varscan2
- ERG | c.969C>T p.F323= (on ENST00000398919 / NM_001243428.1; = p.F299= on NM_004449.4) | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV55732391; called by muse, mutect2, varscan2
- ERICH3 | c.2235C>T p.F745= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as COSV100446011, COSV58600670; called by muse, mutect2, varscan2
- ERP27 | c.90C>T p.S30= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs774640091, COSV56764936; called by muse, mutect2, varscan2
- FAAP100 | c.1149C>T p.P383= | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as rs553681082, COSV59883963; called by muse, mutect2, varscan2
- FAM47C | c.2292G>A p.P764= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs1357638692, COSV63723511; called by muse, mutect2, varscan2
- FAM71B | c.1503C>T p.T501= | Silent (SNP) | VAF 215/560 reads (38%) | catalogued as COSV57231613; called by muse, mutect2, varscan2
- FBXW8 | c.1284G>A p.V428= (on ENST00000309909; = p.V466= on NM_012174.1) | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs767083439, COSV59303882; called by muse, mutect2, varscan2
- FIG4 | c.1491G>A p.Q497= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV57791856; called by muse, mutect2, varscan2
- FLNB | c.2019G>A p.K673= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV55897750; called by muse, mutect2, varscan2
- FLT1 | c.348G>A p.K116= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs758883606, COSV56719409, COSV56744658; called by muse, mutect2, varscan2
- GCK | c.90G>A p.L30= | Silent (SNP) | VAF 337/761 reads (44%) | catalogued as COSV61754248, COSV61754372; called by muse, mutect2, varscan2
- GOLGA6A | c.588C>T p.V196= | Silent (SNP) | VAF 65/343 reads (19%) | catalogued as COSV51807328; called by muse, mutect2, varscan2
- GOLT1B | c.180C>T p.F60= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV57553034; called by muse, mutect2, varscan2
- GRAMD1A | c.531C>T p.F177= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV58769260; called by muse, mutect2, varscan2
- GRIA1 | c.2559C>T p.A853= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV53626702; called by muse, mutect2, varscan2
- GSDMC | c.183C>T p.S61= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV52696569; called by muse, mutect2, varscan2
- GTF2I | c.432C>T p.D144= | Silent (SNP) | VAF 85/215 reads (40%) | catalogued as COSV60404229; called by muse, mutect2, varscan2
- HCCS | c.642C>T p.I214= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV58239816; called by muse, mutect2, varscan2
- HECTD4 | c.8052C>T p.T2684= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV66400611; called by muse, mutect2, varscan2
- HEPH | c.2763T>C p.F921= (on ENST00000343002; = p.F654= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV57973410; called by muse, mutect2, varscan2
- HEPHL1 | c.150G>A p.G50= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs766873666, COSV59889476, COSV59890838; called by muse, mutect2, varscan2
- HHATL | c.1395C>T p.F465= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as rs17852071, COSV55134636; called by muse, mutect2, varscan2
- HOOK2 | c.1152G>A p.E384= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV53404318; called by muse, mutect2, varscan2
- HPX | c.861C>T p.T287= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV56420755, COSV99793588; called by muse, mutect2, varscan2
- HTR1D | c.933C>T p.I311= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV58448976; called by muse, mutect2, varscan2
- HUWE1 | c.3474C>T p.L1158= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV53366126; called by muse, mutect2
- IGBP1 | c.36C>T p.L12= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1186469801, COSV60557488; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.249C>T p.F83= | Silent (SNP) | VAF 94/211 reads (45%) | called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.60G>A p.Q20= | Silent (SNP) | VAF 67/352 reads (19%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.159C>T p.I53= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1173448366; called by muse, mutect2, varscan2
- IL36G | c.342G>A p.V114= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as rs917063043, COSV52078934; called by muse, mutect2, varscan2
- IL6ST | c.2122C>T p.L708= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV100410688, COSV61143120; called by muse, mutect2, varscan2
- INSL3 | c.243C>T p.A81= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs778719109, COSV100427640; called by muse, mutect2, varscan2
- INTS6 | c.1851C>T p.N617= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV60880889; called by muse, mutect2, varscan2
- ITGA5 | c.1209C>T p.D403= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV53221006; called by muse, mutect2, varscan2
- JPH4 | c.1338A>T p.V446= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV58115983; called by muse, mutect2, varscan2
- KCNS3 | c.451C>T p.L151= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as rs376458604; called by muse, mutect2, varscan2
- KIAA0100 | c.5397C>T p.F1799= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV66496833; called by muse, mutect2, varscan2
- KIF21A | c.1188T>C p.L396= | Silent (SNP) | VAF 83/172 reads (48%) | catalogued as COSV62778764; called by muse, mutect2, varscan2
- KIF25 | c.891G>A p.A297= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs762853267, COSV63029164; called by muse, mutect2, varscan2
- KIF7 | c.1872G>A p.E624= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV67999698; called by muse, mutect2, varscan2
- KLF12 | c.633C>T p.V211= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as rs769330172, COSV66577133; called by muse, mutect2, varscan2
- KRT36 | c.1302C>T p.T434= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1223196921, COSV60204891; called by muse, mutect2, varscan2
- L1CAM | c.249T>C p.G83= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV62830436; called by muse, mutect2, varscan2
- LCT | c.381C>T p.P127= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as COSV51469768, COSV99919034; called by muse, mutect2, varscan2
- LDLR | c.1269C>T p.I423= | Silent (SNP) | VAF 88/242 reads (36%) | catalogued as COSV52946293; called by muse, mutect2, varscan2
- LENG8 | c.1650C>T p.I550= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs761941097, COSV58726992; called by muse, mutect2, varscan2
- LGI2 | c.1560G>A p.R520= | Silent (SNP) | VAF 29/33 reads (88%) | catalogued as COSV66123721; called by muse, mutect2, varscan2
- LHFPL5 | c.186C>T p.F62= | Silent (SNP) | VAF 101/180 reads (56%) | catalogued as rs1256085591, COSV64177602; called by muse, mutect2, varscan2
- LPIN2 | c.1413C>T p.L471= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV55244987; called by muse, varscan2
- LRCH4 | c.814C>T p.L272= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs779591158, COSV59644879; called by muse, mutect2, varscan2
- LRRC32 | c.1413G>A p.L471= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV52636044; called by muse, mutect2, varscan2
- LRTM1 | c.360C>T p.S120= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs765487824, COSV55538600; called by muse, mutect2, varscan2
- MAGEC1 | c.1140C>T p.S380= | Silent (SNP) | VAF 114/212 reads (54%) | catalogued as rs1381874970, COSV53582428; called by muse, varscan2
- MAP4K1 | c.408G>A p.R136= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV50263751, COSV50264582; called by muse, mutect2, varscan2
- MASTL | c.756T>A p.P252= | Silent (SNP) | VAF 66/87 reads (76%) | catalogued as COSV60912839; called by muse, mutect2, varscan2
- MCM4 | c.99C>T p.P33= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs199890906, COSV100031918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEGF8 | c.2667C>T p.S889= (on ENST00000251268 / NM_001271938.2; = p.S822= on NM_001410.3) | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs780548431, COSV52103471; called by muse, mutect2, varscan2
- MMAA | c.987C>T p.A329= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as COSV99850079; called by muse, mutect2, varscan2
- MROH2B | c.2733C>T p.I911= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV68182013, COSV68189188; called by muse, mutect2, varscan2
- MRPL9 | c.507C>T p.S169= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV58619906; called by muse, mutect2, varscan2
- MUC20 | c.1944G>A p.T648= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs376392875; called by muse, mutect2, varscan2
- MYCN | c.1092C>T p.P364= | Silent (SNP) | VAF 57/83 reads (69%) | catalogued as rs752702966, COSV55261611; called by muse, mutect2, varscan2
- MYH2 | c.2361G>A p.L787= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as rs776936341, COSV55440575; called by muse, mutect2, varscan2
- MYH3 | c.2511C>T p.I837= | Silent (SNP) | VAF 59/116 reads (51%) | catalogued as COSV56870675; called by muse, varscan2
- MYH8 | c.447G>A p.K149= | Silent (SNP) | VAF 103/246 reads (42%) | catalogued as rs1202079116, COSV67973519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NANOS3 | c.201C>T p.S67= (on ENST00000397555; = p.S86= on NM_001098622.2) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV59250092; called by muse, mutect2, varscan2
- NCR1 | c.309G>C p.G103= | Silent (SNP) | VAF 56/94 reads (60%) | catalogued as COSV52558890; called by muse, mutect2, varscan2
- NF1 | c.5961G>A p.Q1987= (on ENST00000358273 / NM_001042492.3; = p.Q1966= on NM_000267.3) | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs757536610, CD040917, COSV100646381, COSV62223504; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NFRKB | c.3360G>T p.G1120= (on ENST00000446488 / NM_001143835.2; = p.G1145= on NM_006165.3) | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV58760825; called by muse, mutect2, varscan2
- NISCH | c.846C>T p.V282= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV61902614; called by muse, mutect2, varscan2
- NLRP3 | c.1008G>A p.K336= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as rs1408816974, COSV60231787; called by muse, mutect2, varscan2
- NPR1 | c.1459C>T p.L487= | Silent (SNP) | VAF 26/177 reads (15%) | catalogued as COSV64118224; called by muse, mutect2, varscan2
- NRROS | c.201C>T p.N67= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100145654; called by muse, mutect2, varscan2
- NT5E | c.1020G>A p.G340= | Silent (SNP) | VAF 61/102 reads (60%) | catalogued as COSV57628472; called by muse, mutect2, varscan2
- NUBP1 | c.627C>T p.V209= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99297060; called by muse, mutect2, varscan2
- NUMB | c.102C>T p.T34= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as rs116330699; called by muse, mutect2, varscan2
- NUP210L | c.2142G>A p.Q714= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as COSV55144869, COSV55158956; called by muse, mutect2, varscan2
- NWD1 | c.2790G>A p.K930= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs1328416457, COSV60352842; called by muse, mutect2, varscan2
- NXPH2 | c.732C>T p.L244= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV55647333; called by muse, mutect2, varscan2
- OLFML2A | c.489G>A p.E163= | Silent (SNP) | VAF 41/44 reads (93%) | catalogued as COSV56585941; called by muse, mutect2, varscan2
- OPRD1 | c.951C>T p.L317= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1474375069, COSV52384023; called by muse, mutect2, varscan2
- OR10H1 | c.432G>A p.L144= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs763778171, COSV58473229; called by muse, mutect2
- OR10H2 | c.15C>T p.N5= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV59947164; called by muse, mutect2, varscan2
- OR10K1 | c.684C>T p.I228= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs968168734, COSV56870525; called by muse, mutect2, varscan2
- OR11H1 | c.486C>T p.I162= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99421614; called by mutect2, varscan2
- OR13C5 | c.306C>T p.F102= | Silent (SNP) | VAF 51/57 reads (89%) | catalogued as rs753903142, COSV66165421; called by muse, mutect2, varscan2
- OR14I1 | c.336C>T p.F112= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs757750424, COSV61200183; called by muse, mutect2, varscan2
- OR2G2 | c.888G>A p.R296= | Silent (SNP) | VAF 54/203 reads (27%) | catalogued as rs199975925, COSV60741197, COSV60742579; called by muse, mutect2, varscan2
- OR2M5 | c.36C>T p.F12= | Silent (SNP) | VAF 36/263 reads (14%) | catalogued as COSV63547154; called by muse, mutect2, varscan2
- OR3A1 | c.216G>A p.L72= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV60163930; called by muse, mutect2, varscan2
- OR4D1 | c.735C>T p.I245= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs768307995, COSV52126345; called by muse, mutect2, varscan2
- OR4D5 | c.882G>A p.V294= | Silent (SNP) | VAF 61/112 reads (54%) | catalogued as COSV58309796; called by muse, mutect2, varscan2
- OR4K1 | c.909C>T p.N303= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs764530895, COSV53463002; called by muse, varscan2
- OR4X2 | c.672G>A p.G224= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV56585383; called by muse, mutect2, varscan2
- OR51B4 | c.300C>T p.F100= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV66516698, COSV66517269; called by muse, mutect2, varscan2
- OR51B6 | c.459C>T p.S153= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV66514082; called by muse, varscan2
- OR51F2 | c.765C>T p.L255= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1018488108, COSV59066216; called by muse, mutect2, varscan2
- OR52N4 | c.675G>A p.R225= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100421764, COSV57893277; called by muse, mutect2, varscan2
- OR56A3 | c.591C>T p.T197= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV61570208; called by muse, mutect2, varscan2
- OR6Y1 | c.102C>T p.S34= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV56929514; called by muse, mutect2, varscan2
- OR8B12 | c.120G>A p.G40= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs1291656671, COSV60911024; called by muse, mutect2, varscan2
- OR8D2 | c.87C>T p.L29= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV62489156; called by muse, mutect2, varscan2
127 further variants in this file (0 protein-altering or splice-affecting, 107 silent, 20 other) are not listed here.
